CCDI case PBCPCS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/d9126e01-e0c2-438b-9deb-f4d404b4b791

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 1.6 years (587 days).

Biospecimens (2 samples)
- Sample 0DWES2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWESB: Tissue type: Tumor; Specimen type: Solid Tissue.
